Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7IY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7IY-01A (Primary Tumor).

ICD O-3

Oligoastrocytoma, grade III

938213

Site: Brain, supratentorial
NOS C71.0

9/30/13

Glial Tumor with clear signs of malignancy.
IDH R152H mutation present
1p/19q loss present.

Diagnosis: Anaplastic oligoastrocytoma WHO grade III

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file d158be9c-4612-4c52-98ab-da703e518cf1 (TCGA-S9-A7IY.9223C347-C93C-4B31-BEEE-40B481139D7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).